Gene-level copy-number profile of tumor specimen TCGA-D9-A4Z5-01A from TCGA case TCGA-D9-A4Z5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.4 years (24,979 days).
Specimen TCGA-D9-A4Z5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ed6badda-5033-4bdb-8b4b-69a415bfd412.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A4Z5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/559a363b-4a41-4ebe-a005-3570cc26d50b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 1,346; copy number 2: 14,850; copy number 3: 14,635; copy number 4: 21,796; copy number 5: 2,696; copy number 6: 3,571; copy number 7: 652; copy number 8: 65; copy number 9: 69; copy number 10: 16; copy number 12: 8; copy number 13: 20; copy number 15: 3; copy number 17: 27; copy number 18: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A4Z5-01A-11D-A25P-01): tumor purity 0.93, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,674,342–117,794,384, 3 genes (within-gene range 0–2): AC092691.2, LINC02024, AC092691.3.
- chr4:181,064,089–181,591,969, 5 genes: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2.
- chr9:12,098,660–13,836,571, 16 genes (within-gene range 0–4): AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–7): MTAP, AL359922.1.
- chr9:21,892,188–22,824,213, 13 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 158 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:25,579,657–25,938,434, 4 genes, copy number 9–15: AL353730.1, TUSC1, LINC01241, FAM71BP1.
- chr9:26,746,953–27,529,814, 18 genes, copy number 9 (within-gene range 6–9): AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1.
- chr9:34,457,414–34,520,988, 1 gene, copy number 9 (within-gene range 7–9): DNAI1.
- chr9:34,521,043–35,483,035, 47 genes, copy number 9: ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2, CCL19, AL162231.5, CCL21, FAM205A, AL589645.1, FAM205BP, FAM205C, GLULP4, YWHAZP6, PHF24, DNAJB5-DT, DNAJB5, AL355377.1, AL355377.2, SYF2P2, AL355377.3, AL355377.4, AL353795.3, C9orf131, RN7SL338P, VCP, FANCG, PIGO, AL353795.2, STOML2, FAM214B, AL353795.1, UNC13B, AL160274.1, ATP8B5P, ZFAND6P1.
- chr9:35,491,133–35,507,873, 2 genes, copy number 9: AL133476.1, RPL36AP33.
- chr17:9,250,471–9,576,591, 1 gene, copy number 18 (within-gene range 2–18): STX8.
- chr17:9,452,197–14,231,736, 85 genes, copy number 10–18 (within-gene range 7–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 452. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
